Somatic mutation profile of tumor specimen 0DQ80S from CCDI case PBCEML, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.0 years (2,548 days).
Specimen 0DQ80S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3ddc2b1-4a28-4380-8068-0b31751e6e1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7WD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24c64ea8-5adc-4772-b89d-6b9b9ffe8917

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 1, Silent 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 162/604 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514606, COSV55605820, COSV55624598; ClinVar: pathogenic; called by muse, varscan2
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 104/376 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 163/503 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, varscan2
- FOLR2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 87/356 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs141425716; called by muse, varscan2
- MOXD1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 178/436 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as rs768904208, COSV60942573; called by muse, varscan2
- PHKA1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100264023; called by muse, varscan2
- PSD2 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs543972760; called by muse, varscan2
- ABCC5 | c.1091dup p.Y364* | Nonsense Mutation (INS) | VAF 152/609 reads (25%) | called by pindel, varscan2
- C4orf54 | c.3503G>A p.R1168Q | Missense Mutation (SNP) | VAF 75/350 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.773); called by muse, varscan2
- OR1S2 | c.519C>T p.T173= | Silent (SNP) | VAF 152/934 reads (16%) | catalogued as rs764991842; called by muse, varscan2
- GOLGA6L3 | n.877C>T | RNA (SNP) | VAF 14/150 reads (9%) | catalogued as rs1415785176; called by muse, varscan2
- MTMR3 | c.878-90dup | Intron (INS) | VAF 16/85 reads (19%) | catalogued as rs1222049237; called by pindel, varscan2
